Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6928, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6928-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

Patient: XXX

PESEL: XXX

Age: ■

Gender: ■

Material: **Total organ resection – segment of the large intestine**

Unit in charge: ■

Physician in charge: ■

Material collected on: ■

Material received on: ■

Expected time of examination: ■

Clinical diagnosis: **Tumour of the hepatic flexure.**

Examination performed on: ■

Macroscopic description:

An 18 cm length of the large intestine with a piece of the mesentery sized 20 x 7 x 5 cm, with a 7.5 cm length of the small intestine, and a fragment of the omentum sized 11 x 8 x 1,5. A cauliflower-shaped, ulcerous tumour sized 5.5 x 4 x 2.2 cm found in the mucosa. The lesion surrounds 100% of the intestine circumference, narrowing its lumen, is located 10.5 cm from the proximal incision line, 7 cm from the distal incision line, and 3 cm from the Bauhnin's valve. Minimum side margin 6.5 cm.

Microscopic description:

Adenocarcinoma tubulopapillare partim mucinosum (G3).

Infiltratio carcinomatosa tuncae muscularis propriae et telae adiposae pericolicae.

Incision lines clear of neoplastic lesions.

Metastases carcinomatosa in lymphonodis (No III/VI). Infiltratio carcinomatosa telae adiposae perinodalis. Lymphonodulitis reactiva No XVIII).

Adjacent omentum fragment free of cancer.

Histopathological diagnosis:

Adenocarcinoma tubulopapillare partim mucinosum coli. Tubulopapillar and partially mucinous adenocarcinoma of the colon. (G3, Dukes B, Astler-Coller B2, pT3, pNO).

Compliance validated by: ■

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file e038cab1-1e53-4906-8f44-11ad8a700e0c (TCGA-D5-6928.96CFCF3B-2CC8-4EF3-968B-AB7577775BAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).